Somatic mutation profile of tumor specimen C3N-03487-02 (aliquot CPT0194960009) from CPTAC case C3N-03487, project CPTAC-3 (Gum — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,702 days).
Specimen C3N-03487-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dddf386d-b6ef-4a59-8278-2ea43cfea39f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03487-71 (Blood Derived Normal), aliquot CPT0195070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f150ac12-743a-48e8-9ce4-d5d11b49492b

The open-access MAF lists 72 somatic variants for this specimen: 43 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 24, Nonsense Mutation 3, Intron 2, 5'UTR 1, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 58/218 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF2 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as COSV55185252; called by muse, mutect2, varscan2
- ADAMTS8 | c.1846G>A p.G616R | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1280685797; called by muse, mutect2, varscan2
- ATP10A | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV63526063; called by muse, mutect2
- CA5A | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs759583946; called by muse, mutect2, varscan2
- DPP9 | c.490G>A p.D164N (on ENST00000598800; = p.D193N on NM_139159.5) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1214113309, COSV53590008, COSV53593505; called by muse, mutect2
- GCG | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757350391, COSV64961135; called by muse, varscan2
- ITSN2 | c.2404C>G p.Q802E | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV61948760; called by muse, mutect2, varscan2
- MYBPC2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs775004873; called by muse, mutect2
- OR2J3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs775212459, COSV65848879; called by muse, mutect2
- OSBP2 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376816546; called by muse, mutect2, varscan2
- PRKAG3 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs372540696, COSV52102659; called by muse, mutect2
- PTPRN2 | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66104992; called by muse, mutect2
- SCN1A | c.4867G>A p.E1623K (on ENST00000303395 / NM_001202435.3; = p.E1612K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); catalogued as COSV57668913, COSV99066795; called by muse, mutect2
- SDK1 | c.3293C>T p.T1098M | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs558333771, COSV67357885; called by muse, mutect2
- STX8 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as rs752149374, COSV60487682; called by muse, mutect2
- SYNDIG1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs768001570, COSV65232692; called by muse, mutect2
- TET1 | c.1001C>G p.S334* | Nonsense Mutation (SNP) | VAF 19/134 reads (14%) | catalogued as COSV65385094; called by muse, mutect2, varscan2
- TLN1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59205530; called by muse, mutect2
- VWC2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs539846368; called by muse, mutect2, varscan2
- ZNF574 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1404446813; called by muse, mutect2, varscan2
- ADGRA3 | c.3071A>T p.D1024V | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AP1M2 | c.139del p.A47Pfs*4 | Frame Shift Del (DEL) | VAF 44/353 reads (12%) | called by mutect2, pindel, varscan2
- B9D1 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- CCDC39 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- EFCAB12 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ESPL1 | c.5623G>A p.E1875K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2
- FAT3 | c.4129G>A p.V1377M | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTSF1 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- KIF1B | c.2647C>T p.R883W (on ENST00000377086 / NM_001365952.1; = p.R837W on NM_015074.3) | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYBPC1 | c.247G>A p.A83T (on ENST00000550270 / NM_206820.2; = p.A108T on NM_002465.4) | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIF1 | c.6743C>G p.S2248C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.711); called by muse, mutect2
- SHISA2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SHISAL2A | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2
- SLC4A4 | c.2965G>C p.G989R (on ENST00000264485 / NM_001098484.3; = p.G945R on NM_003759.4) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.102); called by muse, mutect2
- SMARCA4 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 47/386 reads (12%) | called by muse, mutect2, varscan2
- TASOR2 | c.1487C>G p.S496* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- TBX21 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TRAF4 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.276); called by muse, mutect2
- TRIP13 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2
- TUBAL3 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF813 | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ACTN3 | c.1188G>T p.L396= | Silent (SNP) | VAF 34/363 reads (9%) | called by muse, mutect2
- CHRNE | c.471C>T p.F157= | Silent (SNP) | VAF 36/312 reads (12%) | called by muse, mutect2, varscan2
- DDX42 | c.1578G>A p.G526= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- EVC2 | c.894C>T p.H298= | Silent (SNP) | VAF 44/584 reads (8%) | catalogued as rs143027693; ClinVar: likely benign; called by muse, mutect2
- FER1L6 | c.5067T>A p.P1689= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2
- GOLGA6B | c.1098G>A p.R366= | Silent (SNP) | VAF 64/517 reads (12%) | called by muse, mutect2, varscan2
- HCRTR1 | c.426G>T p.L142= | Silent (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2, varscan2
- HIVEP2 | c.612G>A p.L204= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV50022836, COSV50077887; called by muse, mutect2, varscan2
- KRBA1 | c.303C>T p.S101= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- LY96 | c.141T>C p.N47= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MAGI3 | c.4233G>T p.L1411= | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- MAMLD1 | c.807G>A p.K269= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2
- MAP4K4 | c.2559C>T p.S853= (on ENST00000347699 / NM_001242559.2; = p.S771= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as rs757774851; called by muse, mutect2
- MREG | c.270C>G p.L90= | Silent (SNP) | VAF 15/156 reads (10%) | called by muse, mutect2
- PCDHGB1 | c.1263C>T p.T421= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as COSV53990810; called by muse, mutect2, varscan2
- PKP1 | c.27C>T p.A9= | Silent (SNP) | VAF 67/499 reads (13%) | called by muse, mutect2, varscan2
- PRDM1 | c.1611G>A p.A537= | Silent (SNP) | VAF 17/215 reads (8%) | catalogued as rs760254920; called by muse, mutect2
- RABL2A | c.72C>A p.I24= | Silent (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- SLITRK2 | c.1503G>A p.L501= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV59424195, COSV59428066; called by muse, mutect2, varscan2
- TRPV4 | c.621C>T p.N207= | Silent (SNP) | VAF 71/420 reads (17%) | catalogued as rs777168770; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.88710C>A p.I29570= (on ENST00000591111; = p.I22146= on NM_003319.4) | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100599280; called by muse, mutect2
- TUBB2B | c.423C>T p.G141= | Silent (SNP) | VAF 10/94 reads (11%) | called by mutect2, varscan2
- VPS18 | c.2035C>T p.L679= | Silent (SNP) | VAF 57/411 reads (14%) | called by muse, mutect2, varscan2
- ZNF614 | c.348C>T p.L116= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- AZGP1 | c.-6G>C | 5'UTR (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- BAGE2 | n.49G>C | RNA (SNP) | VAF 15/347 reads (4%) | called by muse, mutect2
- BAIAP2 | c.1535+512C>T | Intron (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- GDPD2 | c.1307+1036A>G | Intron (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- RNF170 | c.*680T>C | 3'UTR (SNP) | VAF 3/39 reads (8%) | catalogued as rs1334006713; called by muse, mutect2
